Somatic mutation profile of tumor specimen TCGA-02-2466-01A (aliquot TCGA-02-2466-01A-01W-0837-08) from TCGA case TCGA-02-2466, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.5 years (22,457 days).
Specimen TCGA-02-2466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f18c1ca-c48e-45f9-bdd3-2e4a6a20ef07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-02-2466-10A (Blood Derived Normal), aliquot TCGA-02-2466-10A-01W-0837-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c443cf0-f68e-475c-b068-468b8373ec05

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, Intron 2, Frame Shift Ins 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 22/97 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMIGO3 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100246590; called by muse, mutect2, varscan2
- APOB | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99265752; called by muse, mutect2, varscan2
- ATP7B | c.3488G>A p.S1163N | Missense Mutation (SNP) | VAF 110/210 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99666476; called by muse, mutect2, varscan2
- ATR | c.7309C>A p.H2437N | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.755); catalogued as COSV100638266; called by muse, mutect2, varscan2
- ATR | c.7308T>A p.F2436L | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.905); catalogued as COSV100638268; called by muse, mutect2, varscan2
- BOD1L1 | c.1987A>T p.I663F | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99239438; called by muse, mutect2, varscan2
- C1orf141 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.26); catalogued as COSV100924342; called by muse, mutect2, varscan2
- CBLN3 | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99249735; called by muse, mutect2
- CDH8 | c.2081T>A p.F694Y | Missense Mutation (SNP) | VAF 153/287 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100181689; called by muse, mutect2, varscan2
- CDKAL1 | c.1183T>A p.Y395N | Missense Mutation (SNP) | VAF 17/386 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99215471; called by muse, mutect2
- CENPBD1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99240497; called by muse, mutect2, varscan2
- CNGA4 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 265/348 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs753761397, COSV66006215; called by muse, mutect2, varscan2
- COL24A1 | c.2185G>A p.G729R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753008586, COSV100993365; called by muse, mutect2, varscan2
- CSF2RA | c.949T>C p.S317P | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV100817738; called by muse, mutect2
- DAXX | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 100/201 reads (50%) | catalogued as COSV99802137; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 90/97 reads (93%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DHX37 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 114/247 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100439262, COSV58131412; called by muse, mutect2, varscan2
- DNAH1 | c.3488A>G p.D1163G | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV101325867; called by muse, mutect2, varscan2
- DROSHA | c.3226G>C p.E1076Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as rs773151368, COSV100757629; called by muse, mutect2, varscan2
- EAPP | c.760T>C p.Y254H | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99164237; called by muse, mutect2
- ELMO1 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as COSV100164623; called by muse, mutect2, varscan2
- EPHB2 | c.2885G>A p.G962D (on ENST00000400191 / NM_001309193.2; = p.G963D on NM_004442.7) | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101007062; called by muse, mutect2, varscan2
- FAM90A1 | c.1145C>G p.P382R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as COSV100274323; called by muse, mutect2, varscan2
- FAM90A1 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs777845720; called by mutect2, varscan2
- FBXL2 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99371982; called by muse, mutect2, varscan2
- GALK2 | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV100508928; called by muse, mutect2, varscan2
- GRIK5 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543302397, COSV53474625; called by muse, varscan2
- HNRNPDL | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs1479849410, COSV99787102; called by muse, mutect2, varscan2
- ITGA10 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 50/386 reads (13%) | catalogued as COSV100994915; called by muse, mutect2, varscan2
- JMJD1C | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 69/77 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100550582; called by muse, mutect2, varscan2
- KIAA1109 | c.9110A>G p.D3037G | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99164009; called by muse, mutect2, varscan2
- LRP1B | c.13780A>G p.I4594V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs777318122, COSV101257429; called by muse, mutect2, varscan2
- MUC16 | c.29179T>C p.S9727P | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV101200002; called by muse, mutect2, varscan2
- NLRP11 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 111/128 reads (87%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs758380308, COSV100789742; called by muse, mutect2, varscan2
- OBSCN | c.5585T>C p.V1862A | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.5); PolyPhen benign (0.33); catalogued as COSV99478602; called by muse, mutect2, varscan2
- PAK1 | c.688A>G p.T230A | Missense Mutation (SNP) | VAF 83/448 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs780271453, COSV99583456; called by muse, mutect2, varscan2
- PCDHGA6 | c.1382T>C p.V461A | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); catalogued as rs1251456021, COSV99538800; called by muse, mutect2
- PEX1 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 181/535 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs368954584; called by muse, mutect2, varscan2
- PEX5 | c.1839G>A p.M613I (on ENST00000420616; = p.M605I on NM_000319.5) | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs750620715, COSV99870954; called by muse, mutect2
- PIEZO2 | c.7016G>A p.R2339H | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99555018; called by muse, mutect2, varscan2
- PTPN6 | c.1470G>T p.M490I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.338); catalogued as COSV100017115; called by muse, mutect2, varscan2
- PTPRC | c.1948G>T p.G650* | Nonsense Mutation (SNP) | VAF 21/226 reads (9%) | catalogued as COSV100722687; called by muse, mutect2
- PTPRT | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 83/822 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100627458; called by muse, mutect2, varscan2
- RHOBTB3 | c.1630C>G p.H544D | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101183197, COSV66102369; called by muse, mutect2
- RIMS2 | c.1532C>T p.S511L (on ENST00000666250 / NM_001348490.2; = p.S319L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51650842; called by muse, mutect2, varscan2
- RTTN | c.1916T>C p.L639P | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732484; called by muse, mutect2, varscan2
- SACS | c.8693G>A p.R2898H | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs201977288, COSV66538818; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK2 | c.2626A>G p.T876A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV101167686; called by muse, mutect2, varscan2
- SIAE | c.176T>G p.V59G | Missense Mutation (SNP) | VAF 20/461 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99704002, COSV99704063; called by muse, mutect2
- SMARCA4 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60786870; called by muse, mutect2, varscan2
- SUN1 | c.1166G>A p.G389D (on ENST00000405266 / NM_001367651.1; = p.G269D on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1020606766, COSV100568677; called by muse, mutect2, varscan2
- TAL1 | c.899G>A p.S300N | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99596080; called by muse, mutect2, varscan2
- TBC1D8 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 26/207 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100964457; called by muse, mutect2, varscan2
- TCTN3 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99797056; called by muse, mutect2, varscan2
- TIAM2 | c.5171C>G p.T1724R (on ENST00000529824; = p.T1695R on NM_012454.3) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as rs1042011264, COSV99265553; called by muse, mutect2, varscan2
- TMEM104 | c.1187A>G p.D396G | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.952); catalogued as rs1454865458, COSV100120708; called by muse, mutect2, varscan2
- TMEM53 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.363); catalogued as rs369237334; called by muse, mutect2, varscan2
- UEVLD | c.1389_1390del p.H463Qfs*22 | Frame Shift Del (DEL) | VAF 43/104 reads (41%) | catalogued as rs1565102519; called by pindel, varscan2
- USP5 | c.584+2T>C p.X195_splice | Splice Site (SNP) | VAF 33/196 reads (17%) | catalogued as COSV99978638; called by muse, mutect2, varscan2
- XIRP1 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs151258777; called by muse, mutect2, varscan2
- ZNF266 | c.341A>G p.D114G | Missense Mutation (SNP) | VAF 30/677 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100749395; called by muse, mutect2
- ZNF713 | c.368A>G p.D123G (on ENST00000633730 / NM_001366796.2; = p.D136G on NM_182633.3) | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV101448736; called by muse, mutect2
- MYH10 | c.1841_1860del p.F614* | Frame Shift Del (DEL) | VAF 34/132 reads (26%) | called by mutect2, pindel
- PDSS2 | c.1008+1del p.X336_splice | Splice Site (DEL) | VAF 22/83 reads (27%) | called by mutect2, pindel, varscan2
- STX1B | c.849_852del p.G284Rfs*69 | Frame Shift Del (DEL) | VAF 16/82 reads (20%) | called by mutect2, pindel, varscan2
- SYTL1 | c.1063dup p.R355Pfs*14 (on ENST00000543823; = p.R343Pfs*14 on NM_032872.3) | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- CEP41 | c.705G>C p.A235= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV99782732; called by muse, mutect2, varscan2
- CIRBP | c.12T>C p.D4= | Silent (SNP) | VAF 27/427 reads (6%) | catalogued as COSV100309791; called by muse, mutect2
- CLCA1 | c.1419G>A p.G473= | Silent (SNP) | VAF 99/206 reads (48%) | catalogued as rs1406611554, COSV99322396; called by muse, mutect2, varscan2
- CREBBP | c.663A>C p.G221= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV52121550, COSV99270183; called by muse, mutect2, varscan2
- CSMD3 | c.1818C>T p.G606= (on ENST00000297405 / NM_001363185.1; = p.G502= on NM_052900.3) | Silent (SNP) | VAF 38/180 reads (21%) | catalogued as rs373699127; called by muse, varscan2
- DAB1 | c.849G>T p.G283= (on ENST00000371231; = p.G250= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 242/445 reads (54%) | catalogued as COSV100976341, COSV64694301; called by muse, mutect2, varscan2
- DYRK1A | c.816A>G p.A272= | Silent (SNP) | VAF 67/215 reads (31%) | catalogued as COSV100117899; called by muse, mutect2, varscan2
- FAM47B | c.1752C>T p.D584= | Silent (SNP) | VAF 88/340 reads (26%) | catalogued as COSV61452643; called by muse, varscan2
- MAP3K21 | c.861T>C p.I287= | Silent (SNP) | VAF 21/312 reads (7%) | catalogued as COSV100786273; called by muse, mutect2
- MCOLN1 | c.300C>T p.A100= | Silent (SNP) | VAF 143/273 reads (52%) | catalogued as rs1338861801, COSV99900620; called by muse, mutect2, varscan2
- OR4X2 | c.249C>G p.V83= | Silent (SNP) | VAF 55/267 reads (21%) | catalogued as COSV100183246; called by muse, mutect2, varscan2
- POLE | c.6630G>A p.K2210= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs1555301066, COSV100266824; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTPRT | c.1020C>T p.V340= | Silent (SNP) | VAF 98/374 reads (26%) | catalogued as rs765941600, COSV62015241; called by muse, varscan2
- RAB3GAP2 | c.3804T>C p.D1268= | Silent (SNP) | VAF 84/251 reads (33%) | catalogued as rs748424129, COSV100741277; called by muse, mutect2, varscan2
- SLC52A2 | c.864G>A p.A288= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs782702240, COSV100095748; ClinVar: likely benign; called by muse, mutect2, varscan2
- TENM2 | c.3870C>T p.Y1290= (on ENST00000518659 / NM_001122679.2; = p.Y1051= on NM_001080428.3) | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV101318712; called by muse, mutect2, varscan2
- TRBV3-1 | c.228T>C p.N76= | Silent (SNP) | VAF 102/352 reads (29%) | catalogued as rs1011414332; called by muse, mutect2, varscan2
- TRPM7 | c.1971G>A p.K657= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as rs1405514538, COSV57917625; called by muse, mutect2, varscan2
- TRPM8 | c.477G>A p.P159= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV61222147; called by muse, mutect2, varscan2
- ZNF619 | c.672C>T p.T224= | Silent (SNP) | VAF 96/209 reads (46%) | catalogued as COSV100123219; called by muse, mutect2, varscan2
- CARD14 | c.1851+88C>T | Intron (SNP) | VAF 32/60 reads (53%) | catalogued as COSV100712566; called by muse, mutect2, varscan2
- PML | c.1710+817_1710+821del | Intron (DEL) | VAF 48/140 reads (34%) | called by mutect2, pindel, varscan2
- RN7SL176P | chr12:100157231 G>T | 3'Flank (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- VN1R10P | n.642C>G | RNA (SNP) | VAF 168/472 reads (36%) | called by muse, mutect2, varscan2
